Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3837, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3837-01A (Primary Tumor).

Diagnosis

This concerns a tubulovillous adenoma of the colon mucosa with mild dysplasia of the cylindrical epithelium (in I).

II concerns a right hemicolectomy preparation with a slightly differentiated mucinous adenocarcinoma with histopathological differentiation grade G 3, with significant extracellular mucus accumulation, with chronic recurrent inflammation, with acute inflammatory activity, with fine focal necroses, with erosion of the inner surface of the tumor, with tumor infiltration of the colon wall layers up to the pericolic fatty connective tissue, with carcinomatous lymphangitis, with tumor-free lymph nodes (0/36), with moderate chronic lymphadenitis, with chronic appendicitis and with tumor-free overview slices from all other resection sections described.

In relation to the section preparations examined, the spreading of tumor of the colon carcinoma corresponds to tumor stage p T 3, p N 0 (0/36), MX, L1, R0.

Tumor classification:

ICDO-DA M 8480/3

G3

Source: NCI Genomic Data Commons file d0855d6b-34a7-42b5-b61e-640da2cecdfd (TCGA-AA-3837.45D68348-26B2-4A0A-AF72-C741BBF76981.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).